Somatic mutation profile of tumor specimen 0DJHGC from CCDI case PBBVVP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.3 years (4,870 days).
Specimen 0DJHGC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69e408bb-cc50-4f39-857a-32ac1683cf03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHDV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada765ea-4f63-4cf7-8e6e-99cb3667cca0

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf82 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs939887612; called by muse, mutect2
- GRIK2 | c.2342C>A p.A781E | Missense Mutation (SNP) | VAF 24/541 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59709932; called by muse, mutect2
- PKLR | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs981505482, CM941162; called by muse, mutect2, varscan2
- TRPM7 | c.3103G>C p.D1035H | Missense Mutation (SNP) | VAF 36/895 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57916444; called by muse, mutect2
- ABCA13 | c.8140C>T p.H2714Y | Missense Mutation (SNP) | VAF 35/674 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- COPA | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 81/492 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EAPP | c.342A>T p.E114D | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- LMTK3 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC5B | c.6130G>A p.G2044R | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- RASGRP3 | c.1861T>C p.S621P (on ENST00000402538 / NM_001349975.2; = p.S620P on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- RBM48 | c.1005T>G p.H335Q | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- CT47B1 | c.108C>T p.G36= | Silent (SNP) | VAF 26/179 reads (15%) | catalogued as rs751014560, COSV64891512; called by mutect2, varscan2
- DNAH10 | c.6402C>T p.F2134= (on ENST00000409039; = p.F2073= on NM_207437.3) | Silent (SNP) | VAF 52/451 reads (12%) | called by muse, mutect2, varscan2
- HNRNPL | c.831G>A p.K277= | Silent (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- MUC4 | c.14121G>C p.L4707= (on ENST00000463781 / NM_018406.7; = p.L471= on NM_004532.6) | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as rs1275944177; called by muse, mutect2, varscan2
- SEMA7A | c.1473C>T p.D491= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- ZNF727 | c.1269T>G p.P423= | Silent (SNP) | VAF 63/327 reads (19%) | catalogued as COSV70702397; called by muse, mutect2, varscan2
- CTSG | c.204-26C>G | Intron (SNP) | VAF 31/266 reads (12%) | called by muse, mutect2, varscan2
- KXD1 | c.301+73A>C | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- PXDN | c.-1C>T | 5'UTR (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- ZNF738 | chr19:21383121 A>G | 3'Flank (SNP) | VAF 110/516 reads (21%) | called by muse, mutect2, varscan2
